Somatic mutation profile of tumor specimen 0DZ4O0 from CCDI case PBCTUC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,366 days).
Specimen 0DZ4O0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04246fa9-4958-4cdf-a90f-ae4dd2301a3d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZ4MF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/112e0e01-ea23-420d-92e6-5727dc196310

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 2, Frame Shift Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.13841C>A p.S4614Y | Missense Mutation (SNP) | VAF 148/358 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756416108; called by muse, varscan2
- ANKRD44 | c.196del p.R66Vfs*2 | Frame Shift Del (DEL) | VAF 128/326 reads (39%) | catalogued as COSV56567963; called by mutect2, varscan2
- ATP13A2 | c.2755G>C p.V919L | Missense Mutation (SNP) | VAF 178/385 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58699433; called by muse, mutect2, varscan2
- KLK2 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs995514111, COSV57568939; called by muse, mutect2
- MYOM1 | c.1912C>T p.P638S | Missense Mutation (SNP) | VAF 100/231 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772659651; called by muse, mutect2, varscan2
- OR52E1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 118/224 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.05); catalogued as rs745490608; called by muse, mutect2, varscan2
- TMEM132E | c.2317G>A p.V773I (on ENST00000321639; = p.V863I on NM_001304438.2) | Missense Mutation (SNP) | VAF 134/238 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs372908283; called by muse, mutect2, varscan2
- UMODL1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 124/243 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs759890870; called by muse, mutect2, varscan2
- GSE1 | c.3400del p.Q1134Rfs*4 | Frame Shift Del (DEL) | VAF 162/326 reads (50%) | called by mutect2, varscan2
- IFT140 | c.1351G>T p.A451S | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SIAH1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 212/426 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APP | c.1344C>T p.N448= | Silent (SNP) | VAF 147/343 reads (43%) | catalogued as rs776204745, COSV100695632; called by muse, mutect2, varscan2
- MYO7B | c.1485C>A p.T495= | Silent (SNP) | VAF 134/298 reads (45%) | called by muse, mutect2, varscan2
- RCVRN | c.195C>T p.Y65= | Silent (SNP) | VAF 157/358 reads (44%) | catalogued as rs746649664; called by muse, mutect2, varscan2
- SOX6 | c.1047T>C p.N349= | Silent (SNP) | VAF 189/452 reads (42%) | called by muse, mutect2, varscan2
- HNRNPK | c.214-78del | Intron (DEL) | VAF 48/85 reads (56%) | catalogued as COSV104418375; called by mutect2, varscan2
- PLEKHG5 | c.1392+24C>T | Intron (SNP) | VAF 103/210 reads (49%) | catalogued as rs373092930; called by muse, mutect2, varscan2
- SGCA | c.-22G>A | 5'UTR (SNP) | VAF 228/501 reads (46%) | catalogued as rs1374550719; called by muse, mutect2, varscan2
